Gene-level copy-number profile of tumor specimen TCGA-MY-A913-01A from TCGA case TCGA-MY-A913, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 28.4 years (10,379 days).
Specimen TCGA-MY-A913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.ddfd22d5-31ef-4a04-bcd6-c84700484c67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MY-A913-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed0a41cf-6bb9-404a-844c-99bdbc368957

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 5,580; copy number 3: 20,485; copy number 4: 21,610; copy number 5: 5,927; copy number 6: 2,837; copy number 7: 2,395; copy number 8: 2; copy number 9: 351; copy number 10: 178; copy number 11: 394; copy number 16: 2; copy number 61: 40; copy number 79: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MY-A913-01A-11D-A37M-01): tumor purity 0.5, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–14,935,363, 2 genes (within-gene range 0–3): MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 977 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,459,455–131,093,460, 27 genes, copy number 9: POTEI, RNU6-473P, AC013269.2, Metazoa_SRP, CFC1B, AC013269.1, PRSS40B, PRSS40A, AC140481.2, CFC1, Metazoa_SRP, POTEJ, RNU6-848P, CYP4F30P, AC140481.3, FAR2P3, KLF2P3, GPR148, AC140481.1, AMER3, CYCSP8, AC133785.1, ARHGEF4, AC112786.1, AC112786.2, SMIM39, FAM168B.
- chr2:131,177,618–131,181,369, 2 genes, copy number 9: NEK2P4, AC009477.1.
- chr2:131,555,007–135,176,394, 64 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr3:190,322,541–190,449,876, 2 genes, copy number 16 (within-gene range 4–16): CLDN16, TMEM207.
- chr6:485,154–25,930,726, 427 genes, copy number 9–10 (broad region; genes not listed).
- chr11:101,451,564–103,479,863, 52 genes, copy number 61–79: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr19:7,958,573–14,219,605, 355 genes, copy number 11 (broad region; genes not listed).
- chr20:24,962,925–26,251,546, 48 genes, copy number 10: APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
